Somatic mutation profile of tumor specimen TCGA-22-4594-01A (aliquot TCGA-22-4594-01A-01D-1267-08) from TCGA case TCGA-22-4594, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.5 years (22,115 days).
Specimen TCGA-22-4594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9ce9f00-cad5-420f-b01e-99ad0ec31a36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4594-11A (Solid Tissue Normal), aliquot TCGA-22-4594-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfe154fc-8621-436b-87a4-55ec8ddc479e

The open-access MAF lists 356 somatic variants for this specimen: 277 protein-altering or splice-affecting, 71 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 71, Nonsense Mutation 14, Frame Shift Del 9, Splice Site 6, Splice Region 3, 5'Flank 2, Intron 2, RNA 2, 3'UTR 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-19_800del p.X261_splice | Splice Site (DEL) | VAF 20/58 reads (34%) | hotspot (GDC flag); called by mutect2, pindel
- ABCA12 | c.317+2T>A p.X106_splice | Splice Site (SNP) | VAF 52/259 reads (20%) | catalogued as COSV99792091; called by muse, mutect2, varscan2
- ABCA9 | c.2429C>A p.T810N | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100383510; called by muse, mutect2, varscan2
- ABCC8 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs765913448, COSV56851014; called by muse, mutect2, varscan2
- ABCD1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781850760, COSV99497925; ClinVar: uncertain significance; called by muse, mutect2
- ACAN | c.6032C>A p.T2011N | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV100719326; called by muse, mutect2, varscan2
- ADAMTS19 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs760011119, COSV50733404; called by muse, mutect2
- ADAMTS20 | c.3926G>C p.R1309T | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101166398, COSV67126110; called by muse, mutect2, varscan2
- ADAMTS20 | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240390; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 65/538 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99718069, COSV99721266; called by muse, mutect2, varscan2
- ADGRF4 | c.1880A>T p.E627V | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99349036; called by muse, mutect2
- ADGRL3 | c.964C>A p.P322T (on ENST00000506720 / NM_001322402.2; = p.P254T on NM_015236.6) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547400; called by muse, mutect2, varscan2
- ADGRV1 | c.6172A>G p.I2058V | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as COSV101316530; called by muse, mutect2, varscan2
- AFF2 | c.3204G>T p.S1068= | Splice Region (SNP) | VAF 41/174 reads (24%) | catalogued as COSV99666351; called by muse, mutect2, varscan2
- AGPS | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99931736; called by muse, mutect2, varscan2
- AGT | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 19/556 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100794486; called by muse, mutect2
- ANAPC5 | c.1635T>C p.Y545= | Splice Region (SNP) | VAF 23/68 reads (34%) | catalogued as rs559991136, COSV99946499; called by muse, mutect2, varscan2
- ANGPTL1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV99328364; called by muse, mutect2, varscan2
- ANKIB1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs371339261; called by muse, mutect2, varscan2
- ANKRD12 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042131; called by muse, mutect2, varscan2
- ANKRD26 | c.2333A>C p.E778A | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV101063430; called by muse, mutect2
- ANKRD6 | c.1669C>A p.P557T (on ENST00000339746 / NM_001242809.2; = p.P552T on NM_014942.4) | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100330350; called by muse, mutect2, varscan2
- AP3B1 | c.2578-1G>T p.X860_splice | Splice Site (SNP) | VAF 31/301 reads (10%) | catalogued as COSV99672495; called by muse, mutect2, varscan2
- ARHGAP4 | c.876C>A p.S292R | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100604255; called by muse, mutect2
- ARID5A | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.468); catalogued as COSV100673647; called by muse, mutect2, varscan2
- ART5 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 118/541 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV100731720; called by muse, mutect2, varscan2
- ASH2L | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.928); catalogued as COSV99167048; called by muse, mutect2, varscan2
- ASPM | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99661151; called by muse, mutect2, varscan2
- ATP6V1G3 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99811065; called by muse, mutect2, varscan2
- AXDND1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100858678; called by muse, mutect2, varscan2
- BCHE | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.795); catalogued as rs200817146, COSV52259925; called by muse, mutect2, varscan2
- BEND6 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV100876972; called by muse, mutect2, varscan2
- BICD1 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99863027; called by muse, mutect2, varscan2
- BRWD3 | c.3854C>G p.S1285C | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100956559; called by muse, mutect2
- BSDC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100345120; called by muse, mutect2
- C10orf71 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110672; called by muse, mutect2
- C2CD2 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100298424, COSV61600759; called by muse, mutect2
- C2orf66 | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100692843; called by muse, varscan2
- CARNMT1 | c.391A>T p.I131L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100961123; called by muse, mutect2, varscan2
- CASP2 | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60082346; called by muse, mutect2, varscan2
- CCDC33 | c.1522C>A p.H508N | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV99173562; called by muse, mutect2, varscan2
- CCDC39 | c.887C>A p.A296E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99870669; called by muse, mutect2, varscan2
- CCDC88A | c.4024T>A p.L1342M | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99711219; called by muse, mutect2, varscan2
- CCL17 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99537227; called by muse, mutect2, varscan2
- CCN3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99423368; called by muse, mutect2
- CEACAM5 | c.1312C>A p.H438N | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV99704164; called by muse, mutect2, varscan2
- CEP104 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100986373; called by muse, mutect2, varscan2
- CHD7 | c.1367A>T p.Q456L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV101418460; called by muse, mutect2
- CHRM3 | c.1592G>T p.W531L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2
- CHST1 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346542; called by muse, mutect2, varscan2
- CLVS2 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51569769, COSV99253576; called by muse, mutect2, varscan2
- CLYBL | c.63-1G>T p.X21_splice | Splice Site (SNP) | VAF 83/428 reads (19%) | catalogued as rs1198951166, COSV100185727; called by muse, mutect2, varscan2
- CNGA4 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101171882; called by muse, mutect2
- CNTNAP2 | c.2329C>A p.R777S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100673045, COSV62211214; called by muse, mutect2, varscan2
- CNTNAP5 | c.1979G>A p.S660N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV70478013; called by muse, mutect2, varscan2
- COL26A1 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs764888168, COSV100562063; called by muse, mutect2, varscan2
- COL5A1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1442400098, COSV100880596; ClinVar: uncertain significance; called by muse, mutect2
- COL6A2 | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.962); catalogued as COSV100154286, COSV55998338; called by muse, mutect2, varscan2
- COL9A2 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028780; called by muse, mutect2
- CORO7 | c.1168C>T p.R390W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs370284503; called by muse, mutect2, varscan2
- CRB1 | c.4212A>T p.R1404S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100959483; called by muse, mutect2
- CSF1R | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643166; called by muse, mutect2, varscan2
- CSMD3 | c.9187G>T p.G3063C (on ENST00000297405 / NM_001363185.1; = p.G2894C on NM_052900.3) | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99848057; called by muse, mutect2, varscan2
- CTSA | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs746200419, COSV99510150; called by muse, varscan2
- CUL2 | c.1111-2A>T p.X371_splice | Splice Site (SNP) | VAF 38/107 reads (36%) | catalogued as rs1456236029, COSV101039305, COSV66079345; called by muse, mutect2, varscan2
- CYP11B1 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV99455724; called by muse, mutect2, varscan2
- CYP26B1 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV50011047; called by muse, mutect2, varscan2
- DCX | c.931G>T p.G311C (on ENST00000636035 / NM_001195553.2; = p.A311S on NM_000555.3) | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV100576764, COSV57576133; called by muse, mutect2, varscan2
- DCX | c.211del p.A71Lfs*17 | Frame Shift Del (DEL) | VAF 39/335 reads (12%) | catalogued as CM004409, COSV57573184; called by mutect2, pindel, varscan2
- DDR2 | c.595G>C p.G199R | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100906872; called by muse, mutect2, varscan2
- DEPDC4 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV100147427; called by muse, mutect2, varscan2
- DHX57 | c.2426G>A p.G809E | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.56); catalogued as COSV99769964; called by muse, mutect2, varscan2
- DIP2B | c.4339A>T p.T1447S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.331); catalogued as COSV99999408; called by muse, mutect2
- DLG1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100016031; called by muse, mutect2, varscan2
- DLL1 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as rs1353415684, COSV100816120, COSV100816195; called by muse, mutect2, varscan2
- DMD | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99926313, COSV99926330; called by muse, mutect2, varscan2
- DNAH17 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101103501; called by muse, mutect2, varscan2
- DNAH9 | c.7279A>T p.K2427* | Nonsense Mutation (SNP) | VAF 22/195 reads (11%) | catalogued as COSV99308224; called by muse, mutect2, varscan2
- DOCK2 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs1270828281, COSV56970910, COSV99915543; called by muse, mutect2
- DRP2 | c.1790G>C p.R597P | Missense Mutation (SNP) | VAF 113/500 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100872070; called by muse, mutect2, varscan2
- DSC1 | c.638A>C p.Y213S | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99938294; called by muse, mutect2
- DSG3 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV99934740; called by muse, mutect2, varscan2
- DYRK1A | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100118315; called by muse, mutect2, varscan2
- EDAR | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.084); catalogued as COSV99304316; called by muse, mutect2, varscan2
- EFCAB12 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs769894944, COSV58179058; called by muse, mutect2, varscan2
- EPHA3 | c.2302T>C p.S768P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386233725, COSV100348881; called by muse, mutect2, varscan2
- EPHB6 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV101236002; called by muse, varscan2
- FAM170A | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | catalogued as rs776332032, COSV100089345, COSV58926363; called by muse, mutect2
- FAM47A | c.1763C>A p.T588K | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.882); catalogued as COSV100650091; called by muse, varscan2
- FBLN5 | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99969982; called by muse, mutect2
- FBXL3 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV100842399; called by muse, mutect2, varscan2
- FCRL1 | c.884C>A p.T295K | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV100839907; called by muse, mutect2, varscan2
- FGF16 | c.325G>C p.V109L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.262); catalogued as COSV101466327; called by muse, mutect2
- FKBPL | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100913609; called by muse, mutect2, varscan2
- FLG2 | c.3481A>G p.S1161G | Missense Mutation (SNP) | VAF 146/512 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101166236; called by muse, varscan2
- FMNL2 | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV99980910; called by muse, mutect2
- FMR1NB | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100975624; called by muse, mutect2, varscan2
- FOXRED1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 34/160 reads (21%) | catalogued as COSV99703082; called by muse, mutect2, varscan2
- FSIP2 | c.20570C>T p.S6857L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100556586; called by muse, mutect2, varscan2
- FSTL5 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs1318024914, COSV100061312; called by muse, mutect2, varscan2
- FUCA1 | c.1158A>C p.V386= | Splice Region (SNP) | VAF 14/163 reads (9%) | catalogued as COSV100992208; called by muse, mutect2
- FYN | c.1148G>T p.R383L | Missense Mutation (SNP) | VAF 139/535 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV57617560; called by muse, mutect2, varscan2
- FZD2 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100190808; called by muse, mutect2, varscan2
- GAB4 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as rs1380351237, COSV68753940; called by muse, mutect2, varscan2
- GALNT18 | c.287del p.S96Ffs*19 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as COSV57150961; called by mutect2, varscan2
- GANC | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | PolyPhen probably damaging (0.998); catalogued as COSV100531270; called by muse, mutect2, varscan2
- GPLD1 | c.857C>A p.A286E | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV100015590; called by muse, mutect2, varscan2
- GPR137B | c.559A>T p.R187W | Missense Mutation (SNP) | VAF 23/463 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100858407; called by muse, mutect2
- GRIN2B | c.3994G>A p.D1332N | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs200421469, COSV101663192; called by muse, mutect2, varscan2
- GRK7 | c.1573G>T p.G525* | Nonsense Mutation (SNP) | VAF 155/405 reads (38%) | catalogued as COSV99380294; called by muse, mutect2, varscan2
- GRM5 | c.2216G>A p.G739E | Missense Mutation (SNP) | VAF 76/293 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59612888; called by muse, mutect2, varscan2
- H3-5 | c.42del p.A16Pfs*21 | Frame Shift Del (DEL) | VAF 26/185 reads (14%) | catalogued as COSV100461779; called by mutect2, pindel, varscan2
- HBD | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.82); catalogued as CM850035, COSV99496878; called by muse, mutect2
- HEATR1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773705501, COSV63979328; called by muse, mutect2
- HMCN1 | c.3068C>A p.T1023N | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.259); catalogued as COSV99635971; called by muse, mutect2, varscan2
- HMCN1 | c.6874A>G p.I2292V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs1309707539, COSV99635972; called by muse, mutect2
- HOXD13 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101184355; called by muse, mutect2
- HSD17B11 | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as COSV100839636; called by muse, mutect2
- IFIH1 | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718898; called by muse, mutect2, varscan2
- IL13RA1 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV65424549; called by muse, mutect2, varscan2
- ING3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 28/165 reads (17%) | catalogued as COSV100187473; called by muse, mutect2, varscan2
- INSC | c.1568C>G p.P523R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101089231, COSV101089692; called by muse, mutect2, varscan2
- IRAK1 | c.1039C>A p.L347I | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100318523; called by muse, mutect2
- ITGA2 | c.2578G>T p.G860W | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99671651; called by muse, mutect2, varscan2
- ITGA8 | c.967T>C p.Y323H | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100959760; called by muse, mutect2
- ITGB2 | c.474C>A p.N158K | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100186137, COSV56608645; called by muse, mutect2, varscan2
- ITPR1 | c.7589C>T p.T2530M (on ENST00000354582; = p.T2475M on NM_002222.7) | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756574306, COSV57005227; called by muse, mutect2, varscan2
- ITPR3 | c.2827G>T p.A943S | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100968149; called by muse, mutect2
- KAT6A | c.2818C>T p.L940F | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV99705913; called by muse, mutect2
- KCNH1 | c.2195C>G p.P732R (on ENST00000271751 / NM_172362.3; = p.P705R on NM_002238.4) | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV99661552; called by muse, mutect2, varscan2
- KCNRG | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV100078573; called by muse, mutect2, varscan2
- KCNU1 | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101299431, COSV67760345; called by muse, mutect2, varscan2
- KDM4A | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100969663; called by muse, mutect2
- KDM5A | c.5011C>A p.P1671T | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs758258839, COSV101239068; called by muse, mutect2, varscan2
- KLKB1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV99250442; called by muse, mutect2, varscan2
- KRT6B | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99361018; called by muse, varscan2
- LAMP5 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV99855710; called by muse, mutect2, varscan2
- LDLRAD4 | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100762792; called by muse, mutect2, varscan2
- LEFTY2 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100832665; called by muse, mutect2
- LEPR | c.2087G>A p.G696E | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.685); catalogued as COSV60760812; called by muse, mutect2, varscan2
- LMNTD2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs147297012; called by muse, varscan2
- LRP10 | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100612515, COSV62078496; called by muse, varscan2
- LRP4 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs143207358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRK1 | c.1564G>T p.A522S | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52622510; called by muse, mutect2, varscan2
- LUZP1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100035477; called by muse, mutect2
- MAGEL2 | c.2519C>A p.P840H | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as rs780763780, COSV100046217; called by muse, mutect2, varscan2
- MBNL2 | c.990T>A p.S330R | Missense Mutation (SNP) | VAF 19/399 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV100600562; called by muse, mutect2
- MC2R | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763312509, COSV100563209; called by muse, mutect2, varscan2
- MGAT4B | c.738C>A p.N246K | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104393366, COSV99482421; called by muse, mutect2
- MKX | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.109); catalogued as COSV101008890; called by muse, varscan2
- MMRN1 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.443); catalogued as COSV99307777; called by muse, mutect2, varscan2
- MMS22L | c.863G>C p.C288S | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.154); catalogued as COSV99247771; called by muse, mutect2
- MTNR1B | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 39/141 reads (28%) | catalogued as COSV99925363; called by muse, mutect2, varscan2
- MUC17 | c.4306T>A p.S1436T | Missense Mutation (SNP) | VAF 62/846 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs878945055; called by muse, mutect2
- MUC5B | c.7543A>T p.S2515C | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101500779; called by muse, mutect2, varscan2
- MYH8 | c.5147T>A p.V1716D | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101238808; called by muse, mutect2, varscan2
- MYH8 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101238811; called by muse, mutect2
- MYO15A | c.4390G>T p.V1464L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV99231998, COSV99234461; called by muse, mutect2, varscan2
- MYOM2 | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100038421; called by muse, mutect2, varscan2
- MYOM3 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs1167055831, COSV100293910; called by muse, mutect2
- NALCN | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV99216469, COSV99217816; called by muse, mutect2
- NEFM | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647582; called by muse, mutect2, varscan2
- NEGR1 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV100166231; called by muse, mutect2, varscan2
- NELL1 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs778944309, COSV100125331, COSV54301137; called by muse, mutect2, varscan2
- NF1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.838); catalogued as rs876659418, COSV62219865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFE2L2 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 80/368 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV101229446; called by muse, mutect2, varscan2
- NLGN3 | c.2369C>T p.P790L (on ENST00000358741 / NM_181303.2; = p.P770L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs867369348, COSV100705059; called by muse, mutect2
- NLRP3 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV100276672; called by muse, mutect2, varscan2
- NPAP1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 182/705 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1176202414, COSV100276390, COSV61508540; called by muse, mutect2, varscan2
- NPLOC4 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV100481230; called by muse, mutect2, varscan2
- NRIP2 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV99958346; called by muse, varscan2
- OGT | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101035643; called by muse, mutect2, varscan2
- OR10C1 | c.571G>T p.G191* (on ENST00000622521; = p.G189* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 176/583 reads (30%) | catalogued as COSV101010800, COSV65824456; called by muse, mutect2, varscan2
- OR10J3 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV100171889, COSV59954734; called by muse, mutect2
- OR2T27 | c.27T>A p.Y9* | Nonsense Mutation (SNP) | VAF 17/151 reads (11%) | catalogued as COSV100788411; called by muse, mutect2, varscan2
- OR2T3 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 56/638 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.417); catalogued as rs775000698, COSV100613423; called by muse, mutect2
- OR5D16 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV101004148; called by muse, mutect2, varscan2
- OR7D2 | c.753T>A p.F251L | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV100713082; called by muse, mutect2
- OR8D2 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV100659114; called by muse, mutect2, varscan2
- PAPPA2 | c.3466A>T p.S1156C | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100868668; called by muse, mutect2, varscan2
- PCDH8 | c.4A>T p.S2C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV100132058; called by muse, mutect2, varscan2
- PCDHB5 | c.1761G>T p.K587N | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99169590; called by muse, mutect2, varscan2
- PCDHB5 | c.1762G>T p.V588L | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99169591; called by muse, mutect2, varscan2
- PDX1 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV101124115; called by muse, mutect2, varscan2
- PGRMC1 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99483619; called by muse, mutect2, varscan2
- PHACTR3 | c.1014G>C p.E338D | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100733240; called by muse, mutect2, varscan2
- PIK3R3 | c.79A>T p.I27L | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.024); catalogued as COSV99422939; called by muse, mutect2
- PLCL1 | c.2506A>T p.M836L | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101407297; called by muse, mutect2, varscan2
- PLXNB3 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.138); catalogued as COSV100737946, COSV104423398; called by muse, mutect2
- PMS2 | c.1550G>C p.S517T | Missense Mutation (SNP) | VAF 99/347 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV99764577; called by muse, mutect2, varscan2
- PNLDC1 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV99277898; called by muse, mutect2
- PODN | c.1048C>T p.R350W (on ENST00000395871; = p.R302W on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs775002974, COSV100439850; called by muse, mutect2
- PREP | c.802G>T p.E268* (on ENST00000369110; = p.E334* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 36/306 reads (12%) | catalogued as COSV100964120; called by muse, mutect2, varscan2
- PRKCA | c.977A>C p.Q326P | Missense Mutation (SNP) | VAF 66/844 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99436272; called by muse, mutect2
- PSEN2 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200410369, COSV100423302; called by muse, mutect2, varscan2
- PTPRU | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs145823140; called by muse, mutect2, varscan2
- RANBP17 | c.3001G>C p.V1001L | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101206388; called by muse, mutect2
- RASL11A | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV99611173; called by muse, mutect2, varscan2
- RBMXL2 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.642); catalogued as COSV100182311; called by muse, mutect2, varscan2
- RNASEL | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 75/408 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV100842656; called by muse, mutect2, varscan2
- RORB | c.1274C>A p.P425Q (on ENST00000396204 / NM_001365023.1; = p.P414Q on NM_006914.4) | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100974597; called by muse, mutect2
- RSPO3 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100759661; called by muse, mutect2, varscan2
- RYR1 | c.6260A>G p.E2087G | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV100617041; called by muse, mutect2, varscan2
- RYR2 | c.5723T>A p.L1908Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100772933; called by muse, mutect2, varscan2
- SATL1 | c.437C>A p.P146Q (on ENST00000395409; = p.P333Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV100261114; called by muse, mutect2, varscan2
- SCN7A | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101313367, COSV69271716; called by muse, mutect2
- SEL1L2 | c.1471A>G p.K491E | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99533948; called by muse, mutect2, varscan2
- SELL | c.599A>G p.Y200C (on ENST00000650983; = p.Y187C on NM_000655.5) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs908211782, COSV99357828; called by muse, mutect2, varscan2
- SERPING1 | c.899A>T p.K300M | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs755095483, COSV53542293, COSV99558178; called by muse, mutect2, varscan2
- SH3PXD2A | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 20/379 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100280537; called by muse, mutect2
- SIPA1L1 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs780750174, COSV100666077; called by muse, mutect2
- SIRPA | c.1301T>A p.L434Q | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100605420; called by muse, mutect2, varscan2
- SLC17A7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 287/827 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99677073; called by muse, varscan2
- SLC26A5 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100100208; called by muse, varscan2
- SLC45A1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.098); catalogued as rs145948582; called by mutect2, varscan2
- SLC6A12 | c.1285G>C p.A429P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100675224; called by muse, varscan2
- SLC8A1 | c.2561A>T p.K854I | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100247464; called by muse, mutect2, varscan2
- SLC9A2 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 100/481 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV99296862; called by muse, mutect2, varscan2
- SLIT3 | c.3835C>G p.L1279V | Missense Mutation (SNP) | VAF 83/586 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100270009; called by muse, mutect2, varscan2
- SLITRK2 | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 69/335 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100158224; called by muse, mutect2, varscan2
- SMARCA2 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61812101; called by muse, mutect2, varscan2
- SMARCD3 | c.1023C>G p.I341M (on ENST00000262188 / NM_001003801.2; = p.I328M on NM_003078.4) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99223242, COSV99223352; called by muse, mutect2
- SP140 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100614107; called by muse, mutect2
- SP140 | c.2412C>G p.I804M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100613545; called by mutect2, varscan2
- SPHKAP | c.3615C>G p.D1205E | Missense Mutation (SNP) | VAF 148/510 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1475864522, COSV100764539; called by muse, mutect2, varscan2
- SPTA1 | c.6215G>T p.C2072F | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100935598; called by muse, mutect2, varscan2
- SRGAP3 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs761039298, COSV100841451; called by muse, mutect2, varscan2
- STIP1 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99656826; called by muse, mutect2
- STRADB | c.763G>T p.G255W | Missense Mutation (SNP) | VAF 125/524 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52043484, COSV99524802; called by muse, mutect2, varscan2
- STYXL2 | c.2178G>T p.W726C | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99609907; called by muse, mutect2, varscan2
- SUCO | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV99743849; called by muse, mutect2
- TCF25 | c.466A>T p.R156W | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99642622, COSV99643455; called by muse, mutect2, varscan2
- TEX15 | c.2791C>G p.P931A (on ENST00000256246; = p.P1314A on NM_001350162.2) | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99822144; called by muse, mutect2, varscan2
- TLR7 | c.3006G>C p.Q1002H | Missense Mutation (SNP) | VAF 153/747 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV101028148; called by muse, mutect2, varscan2
- TMPRSS13 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV101471501; called by muse, mutect2
- TMX1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as COSV100790063; called by muse, mutect2
- TPPP | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs758647631, COSV100862902; called by muse, mutect2, varscan2
- TPSAB1 | c.221A>T p.H74L | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100127221; called by muse, mutect2, varscan2
- TRANK1 | c.3732G>T p.W1244C | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100084832; called by muse, mutect2, varscan2
- TRIM17 | c.1246A>T p.S416C | Missense Mutation (SNP) | VAF 50/277 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99489022; called by muse, mutect2, varscan2
- TRIM38 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100837648; called by muse, mutect2
- TRIM39 | c.660G>T p.Q220H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV100935922; called by muse, mutect2, varscan2
- TRPA1 | c.2696G>T p.S899I | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV100085220; called by muse, mutect2, varscan2
- TRUB2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1011111197, COSV55957686; called by muse, mutect2
- TSNAXIP1 | c.142T>A p.L48M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101183915; called by muse, mutect2, varscan2
- TTI1 | c.1864A>G p.S622G | Missense Mutation (SNP) | VAF 79/431 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.793); catalogued as COSV100989759; called by muse, mutect2, varscan2
- TTN | c.14417T>A p.L4806* (on ENST00000591111; = p.L3879* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 86/271 reads (32%) | catalogued as COSV100630520; called by muse, mutect2, varscan2
- UBE2W | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100709023; called by muse, mutect2
- UBL4A | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 96/478 reads (20%) | catalogued as COSV99682236; called by muse, mutect2, varscan2
- UMOD | c.1578-1G>T p.X526_splice | Splice Site (SNP) | VAF 26/139 reads (19%) | catalogued as COSV100208700; called by muse, mutect2, varscan2
- UNC13A | c.3395C>A p.P1132H | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53187050, COSV99409606; called by muse, mutect2, varscan2
- UNC5D | c.694A>T p.M232L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99778854; called by muse, mutect2, varscan2
- USP29 | c.1399T>A p.L467M | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as COSV99518691; called by muse, mutect2, varscan2
- UTS2R | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100493406, COSV57452786; called by muse, mutect2, varscan2
- VGLL1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 131/512 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV101034731; called by muse, mutect2, varscan2
- VKORC1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as rs775979722, COSV99762674; called by muse, mutect2, varscan2
- VWC2 | c.762T>A p.C254* | Nonsense Mutation (SNP) | VAF 54/234 reads (23%) | catalogued as COSV100514790; called by muse, mutect2, varscan2
- VWF | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs932271358, CM163340, COSV99780191; called by muse, mutect2, varscan2
- WNT7B | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100255313, COSV59752974; called by muse, mutect2, varscan2
- XIRP2 | c.8474C>A p.A2825D (on ENST00000628543; = p.A3000D on NM_152381.6) | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99745728, COSV99747575; called by muse, mutect2, varscan2
- YTHDC1 | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); catalogued as COSV100704868; called by mutect2, varscan2
- ZIM2 | c.792A>T p.K264N | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99690423; called by muse, mutect2, varscan2
- ZNF438 | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV100062759, COSV59194694; called by muse, mutect2, varscan2
- ZNF479 | c.1399T>A p.C467S | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV58638444; called by muse, mutect2, varscan2
- ZNF530 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 13/278 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as COSV100252762; called by muse, mutect2
- ZNF804B | c.3131G>T p.R1044M | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100306290; called by muse, mutect2, varscan2
- ZNF831 | c.2600G>T p.G867V | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV100926271; called by muse, mutect2, varscan2
- ABCC4 | c.3781_3782dup p.L1261Ffs*59 | Frame Shift Ins (INS) | VAF 75/288 reads (26%) | called by mutect2, pindel, varscan2
- ARID2 | c.2408del p.G803Afs*19 | Frame Shift Del (DEL) | VAF 17/146 reads (12%) | called by mutect2, pindel, varscan2
- ESPL1 | c.4531del p.E1511Kfs*24 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- KEAP1 | c.954del p.C319Afs*9 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel*, varscan2
- KMO | c.1232_1240delinsAGGCT p.A411Efs*10 | Frame Shift Del (DEL) | VAF 78/318 reads (25%) | called by pindel, varscan2*
- NFS1 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2
- RAPGEF3 | c.2335A>G p.K779E (on ENST00000389212; = p.K737E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- RGS6 | c.1207del p.D403Ifs*7 | Frame Shift Del (DEL) | VAF 33/180 reads (18%) | called by mutect2, pindel, varscan2
- SARM1 | c.1843C>G p.R615G | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- SLC6A17 | c.2088del p.G698Afs*83 | Frame Shift Del (DEL) | VAF 59/258 reads (23%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1560G>T p.G520= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV100751157; called by muse, mutect2, varscan2
- ACAD10 | c.1491C>T p.A497= | Silent (SNP) | VAF 63/252 reads (25%) | catalogued as COSV100564630; called by muse, mutect2, varscan2
- ACER1 | c.288G>T p.L96= | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as COSV100034134; called by muse, mutect2, varscan2
- AMPH | c.240G>T p.S80= | Silent (SNP) | VAF 62/250 reads (25%) | catalogued as COSV100343695, COSV57744871; called by muse, mutect2, varscan2
- ASXL1 | c.2424T>A p.P808= | Silent (SNP) | VAF 55/320 reads (17%) | catalogued as COSV100041194; called by muse, mutect2, varscan2
- ATP6V1G3 | c.51G>C p.R17= | Silent (SNP) | VAF 46/253 reads (18%) | catalogued as COSV99811069; called by muse, mutect2, varscan2
- C8A | c.501G>T p.V167= | Silent (SNP) | VAF 42/238 reads (18%) | catalogued as COSV100776664; called by muse, mutect2, varscan2
- CAGE1 | c.648T>C p.S216= (on ENST00000512086; = p.S80= on NM_205864.3) | Silent (SNP) | VAF 32/450 reads (7%) | catalogued as COSV99700178; called by muse, mutect2
- CNTF | c.486G>A p.L162= | Silent (SNP) | VAF 19/244 reads (8%) | catalogued as COSV100284754; called by muse, mutect2
- CNTN2 | c.2340C>A p.P780= | Silent (SNP) | VAF 46/239 reads (19%) | catalogued as COSV100085500; called by muse, mutect2, varscan2
- COL6A3 | c.6825C>A p.P2275= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as COSV99801560; called by muse, mutect2, varscan2
- CSMD2 | c.3159G>A p.L1053= | Silent (SNP) | VAF 64/265 reads (24%) | catalogued as COSV99595512; called by muse, mutect2, varscan2
- CTNND1 | c.2694A>G p.K898= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100650292; called by muse, mutect2, varscan2
- DLL1 | c.1053C>A p.S351= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV100816115; called by muse, mutect2, varscan2
- ELP4 | c.429T>C p.D143= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as rs1418168022, COSV100635896; called by muse, mutect2
- FAM155B | c.1294C>A p.R432= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as COSV99368690, COSV99368692; called by muse, mutect2
- FGGY | c.1077C>T p.C359= | Silent (SNP) | VAF 64/320 reads (20%) | catalogued as COSV100365934; called by muse, mutect2, varscan2
- FGL2 | c.181C>T p.L61= | Silent (SNP) | VAF 46/319 reads (14%) | catalogued as COSV99593161; called by muse, mutect2, varscan2
- FIBIN | c.408C>A p.S136= | Silent (SNP) | VAF 48/259 reads (19%) | catalogued as rs750251302, COSV100590532; called by muse, mutect2, varscan2
- GJB6 | c.741G>T p.L247= | Silent (SNP) | VAF 93/586 reads (16%) | catalogued as COSV99576162; called by muse, mutect2, varscan2
- GPR84 | c.543C>A p.I181= | Silent (SNP) | VAF 53/230 reads (23%) | catalogued as COSV99910139; called by muse, mutect2, varscan2
- GRM6 | c.2580C>T p.A860= | Silent (SNP) | VAF 73/388 reads (19%) | catalogued as rs1295843003, COSV99179958; called by muse, mutect2, varscan2
- GUCY2D | c.2805G>A p.S935= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as rs774560137, COSV99644285; called by muse, mutect2, varscan2
- IQGAP3 | c.4272A>C p.S1424= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs777137475, COSV100752387; called by muse, mutect2, varscan2
- KCNQ3 | c.1383A>G p.P461= | Silent (SNP) | VAF 154/374 reads (41%) | catalogued as COSV101196452; called by muse, mutect2, varscan2
- KRTAP13-2 | c.30C>T p.F10= | Silent (SNP) | VAF 23/368 reads (6%) | catalogued as COSV101299640, COSV101299675; called by muse, mutect2
- LCT | c.5313T>G p.T1771= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV99930487; called by muse, mutect2, varscan2
- LRP1B | c.7884A>G p.T2628= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV101261239, COSV67265463; called by muse, mutect2, varscan2
- LRRC37B | c.1989C>T p.R663= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV58951730; called by muse, mutect2, varscan2
- LRRTM1 | c.375C>A p.I125= | Silent (SNP) | VAF 66/354 reads (19%) | catalogued as COSV54438205, COSV99703209; called by muse, mutect2, varscan2
- MAP3K10 | c.1740G>T p.G580= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99454872; called by muse, mutect2, varscan2
- MEN1 | c.480C>T p.S160= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs936786553, COSV53643666; ClinVar: likely benign; called by muse, mutect2
- MTOR | c.2112G>T p.V704= | Silent (SNP) | VAF 38/168 reads (23%) | catalogued as COSV100816690; called by muse, mutect2, varscan2
- MTUS2 | c.1515T>C p.S505= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV101462373; called by muse, mutect2, varscan2
- MXRA5 | c.7746C>T p.T2582= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs138427941, COSV54224814; called by muse, mutect2, varscan2
- NCKAP1L | c.3084C>T p.N1028= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV99515720; called by muse, mutect2, varscan2
- NFS1 | c.1020G>C p.V340= | Silent (SNP) | VAF 76/298 reads (26%) | catalogued as COSV100932021; called by muse, mutect2, varscan2
- NLGN4X | c.2067C>T p.N689= | Silent (SNP) | VAF 66/327 reads (20%) | catalogued as COSV99323984; called by muse, mutect2, varscan2
- NRXN2 | c.2697T>A p.G899= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99635855; called by muse, mutect2, varscan2
- NUP210L | c.2838A>G p.E946= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as COSV99669151; called by muse, mutect2
- OR2AK2 | c.321T>C p.L107= | Silent (SNP) | VAF 66/1176 reads (6%) | catalogued as rs1232803112, COSV100824338; called by muse, mutect2
- OR2T4 | c.882C>A p.P294= | Silent (SNP) | VAF 30/470 reads (6%) | catalogued as COSV100822627; called by muse, mutect2
- OR4N2 | c.783C>A p.P261= | Silent (SNP) | VAF 13/324 reads (4%) | catalogued as COSV100270032; called by muse, mutect2
- OR5M1 | c.642T>A p.I214= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV101591612; called by muse, mutect2
- OR6K2 | c.429G>T p.L143= | Silent (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100656888; called by muse, mutect2, varscan2
- OR9A2 | c.675G>T p.P225= | Silent (SNP) | VAF 65/180 reads (36%) | catalogued as rs141056346, COSV100628162, COSV100628289; called by muse, varscan2
- OSTN | c.234A>G p.T78= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as COSV100174343; called by muse, mutect2, varscan2
- PKLR | c.996C>A p.G332= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV100713033; called by muse, mutect2, varscan2
- PLB1 | c.1836T>A p.I612= | Silent (SNP) | VAF 39/255 reads (15%) | catalogued as rs369090810; called by muse, mutect2, varscan2
- POLRMT | c.2941C>T p.L981= | Silent (SNP) | VAF 29/445 reads (7%) | catalogued as rs376825536; called by muse, mutect2
- PPIAL4G | c.153C>A p.S51= | Silent (SNP) | VAF 113/528 reads (21%) | catalogued as COSV101344027; called by muse, mutect2, varscan2
- PSMA4 | c.327G>A p.Q109= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV99245636; called by muse, mutect2
- RNF6 | c.1119G>T p.V373= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV60419869; called by muse, mutect2, varscan2
- RP1L1 | c.4473G>T p.T1491= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV66752557; called by muse, mutect2, varscan2
- RTL3 | c.681C>A p.A227= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100330105; called by muse, mutect2, varscan2
- RTL9 | c.1986C>A p.A662= | Silent (SNP) | VAF 51/257 reads (20%) | catalogued as COSV101511800; called by muse, mutect2, varscan2
- SAMD4A | c.519G>A p.Q173= | Silent (SNP) | VAF 13/168 reads (8%) | catalogued as COSV99200840; called by muse, mutect2
- SIDT1 | c.2370C>T p.D790= | Silent (SNP) | VAF 34/502 reads (7%) | catalogued as COSV99334729; called by muse, mutect2
- SIPA1L2 | c.3597G>T p.L1199= | Silent (SNP) | VAF 392/1860 reads (21%) | catalogued as rs1305261914, COSV99479736; called by muse, mutect2, varscan2
- SLITRK3 | c.2160G>T p.G720= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as rs777446974, COSV99579093, COSV99580206; called by muse, mutect2, varscan2
- TCHH | c.4944G>A p.E1648= | Silent (SNP) | VAF 80/298 reads (27%) | catalogued as COSV100915491; called by muse, mutect2, varscan2
- TCN1 | c.108A>G p.L36= | Silent (SNP) | VAF 36/454 reads (8%) | catalogued as COSV99953473; called by muse, mutect2
- TMEM145 | c.583C>T p.L195= | Silent (SNP) | VAF 46/520 reads (9%) | catalogued as COSV100004140; called by muse, mutect2
- TRIP12 | c.2488C>T p.L830= | Silent (SNP) | VAF 117/417 reads (28%) | catalogued as COSV99390963; called by muse, mutect2, varscan2
- TULP4 | c.2769C>T p.A923= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as rs1218934304, COSV100893845; called by muse, mutect2, varscan2
- TXN2 | c.399G>T p.V133= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV99340566; called by muse, mutect2, varscan2
- UBE2U | c.546A>G p.T182= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs757936881, COSV100934525; called by muse, mutect2, varscan2
- USH2A | c.6204C>A p.P2068= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV100231259, COSV56336351; called by muse, mutect2, varscan2
- ZGRF1 | c.3597T>A p.S1199= | Silent (SNP) | VAF 123/385 reads (32%) | catalogued as COSV100481355; called by muse, mutect2, varscan2
- ZNF493 | c.1656T>G p.T552= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100828939; called by muse, varscan2
- ZNF592 | c.1989G>T p.V663= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as COSV100246133; called by muse, mutect2
- ASB4 | c.978+47C>A | Intron (SNP) | VAF 35/105 reads (33%) | catalogued as COSV100367310; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1081G>T | 3'UTR (SNP) | VAF 45/335 reads (13%) | catalogued as COSV100247326; called by muse, mutect2, varscan2
- C1orf216 | chr1:35720895 C>A | 5'Flank (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99231542; called by muse, varscan2
- C1orf216 | chr1:35720896 C>A | 5'Flank (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99231544; called by muse, mutect2, varscan2
- CFLAR | c.1305-779A>G | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as rs1165673940, COSV100009911; called by muse, mutect2
- DELEC1 | n.592G>T | RNA (SNP) | VAF 58/171 reads (34%) | catalogued as COSV100927027; called by muse, mutect2, varscan2
- SEL1L2 | c.*1G>T | 3'UTR (SNP) | VAF 24/286 reads (8%) | catalogued as rs766068262, COSV99533946; called by muse, mutect2
- SNORD113-3 | n.62C>A | RNA (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
